Surgical pathology report (de-identified scan), TCGA case TCGA-ZP-A9CY, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-ZP-A9CY-01A (Primary Tumor).

[page 1 of 2]
Results History

SURG PATH FINAL REPORT

Entry Information

Entry Date and Time

Lab Status
Final result

Entered by

Component Results

Component

SURG PATH FINAL REPORT

ICD O-3

Carcinoma, hepatocellular NOS 8170/3
Site: Liver C22.0
JW 2/3/14

Accession #:

Specimen:

- A. Left lateral liver segment FS
- B. Left lateral liver segment

Clinical Notes:

Liver lesions. Hx of NASH cirrhosis. Specimen B: Fresh tissue saved for tissue bank.

Diagnosis:

- A. Liver, left lateral segment, lesion, frozen section biopsy:
- Hepatocellular carcinoma, well-differentiated.
- B. Liver, left lateral segment, lesion, excision:
- Hepatocellular carcinoma, well-differentiated (2.8 cm), completely excised.
- pT1 NX MX.
- No lymphovascular invasion identified.
- Macronodular cirrhosis with steatohepatitis (grade 1, stage 4).

(Electronically signed by)

Verified:

Gross:

A. The specimen is labeled "left lateral liver segment." Received fresh for frozen section is a 2.8 x 1.7 x 0.4 cm fragment of pink-tan soft tissue. The specimen is submitted in toto for frozen section. The frozen section remnant is resubmitted for permanent in cassette A.

B. The specimen is labeled "left lateral liver segment." Received in is a 17.9 gram, 7.0 x 3.4 x 2.4 cm, wedge of liver tissue. The specimen is mostly covered by a pink capsule, and exhibits a nodular appearance. The specimen is marked with black ink on the parenchymal resection margin and serially sectioned to reveal a nodular,

[page 2 of 2]
[REDACTED]

pink-yellow-tan cut surface. A single dominant nodule is present, 2.8 x 2.5 x 2.0 cm. This nodule is 0.3 cm from the nearest parenchymal resection margin and exhibits a soft, yellow-tan to pink-red cut surface. A small amount of grossly uninvolved pink-tan liver parenchyma is present. A portion of fresh tissue is sent tissue bank.

Accession #:

Representative sections are submitted in cassettes B1 through B6.

Intraoperative Consultation:

FROZEN SECTION:

A. Cirrhosis, negative for malignancy.

Microscopic:

A histologic examination was performed.

CPT:

No charge codes are associated with this case.

Entry Information

Entry Date and Time

Lab Status
In process

Entered by

[REDACTED]

Source: NCI Genomic Data Commons file 8e93be40-2360-4e8b-b3b1-a60c37780288 (TCGA-ZP-A9CY.849947D6-678A-4536-A5FB-9A56489C8D3E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).